Somatic mutation profile of tumor specimen ALCH-B2MR-TTP1-A (aliquot ALCH-B2MR-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2MR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,788 days).
Specimen ALCH-B2MR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ab8e462-310d-4903-a675-9b21cb67ea2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MR-NB1-A (Blood Derived Normal), aliquot ALCH-B2MR-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c1622a-d41b-451e-a8c0-ac5d2f262756

The open-access MAF lists 539 somatic variants for this specimen: 368 protein-altering or splice-affecting, 113 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 113, Nonsense Mutation 36, Intron 21, RNA 16, Frame Shift Del 11, 5'UTR 9, Splice Region 9, Splice Site 8, 3'UTR 7, 5'Flank 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2839-1G>C p.X947_splice | Splice Site (SNP) | VAF 32/258 reads (12%) | catalogued as rs386833569, CS061291, COSV58686436; ClinVar: likely pathogenic; called by muse, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 55/165 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as rs121913317, COSV58822577, COSV58822973, COSV58827104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 211/572 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121912667, CM083790, COSV52676438, COSV53038615, COSV53625652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1536+1G>T p.X512_splice (on ENST00000404938 / NM_001163941.2; = p.X67_splice on NM_178559.6) | Splice Site (SNP) | VAF 23/88 reads (26%) | catalogued as COSV51715027; called by muse, varscan2
- ACAN | c.6545C>G p.P2182R | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs551246840; called by muse, mutect2, varscan2
- ACVR1B | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57777416; called by muse, mutect2
- ADCY1 | c.2656G>T p.G886C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52033055; called by muse, mutect2, varscan2
- AGO1 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100940968; called by muse, mutect2
- AGRN | c.2611G>T p.G871W | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756920232; called by muse, mutect2, varscan2
- AHNAK2 | c.11869G>A p.A3957T | Missense Mutation (SNP) | VAF 88/661 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV60920091; called by muse, mutect2
- AIPL1 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 149/384 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201168635; called by muse, mutect2, varscan2
- AKAP13 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV63455163; called by muse, varscan2
- ANKRD30A | c.964G>T p.E322* (on ENST00000611781; = p.E266* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 129/377 reads (34%) | catalogued as COSV64608757; called by muse, mutect2, varscan2
- ARHGEF12 | c.3986G>T p.R1329L | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100755005, COSV63104928; called by muse, mutect2, varscan2
- ASNSD1 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1318295907; called by muse, mutect2, varscan2
- ATRIP | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.605); catalogued as COSV104411060; called by muse, mutect2, varscan2
- BACH2 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV57596362; called by muse, mutect2, varscan2
- BIN2 | c.1414C>G p.P472A | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs944302833; called by muse, mutect2, varscan2
- BLOC1S3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.548); catalogued as rs1443188282; called by muse, mutect2
- BOC | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs149108723; called by muse, mutect2, varscan2
- C9orf85 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58253753; called by muse, mutect2, varscan2
- CD6 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV57836594; called by muse, varscan2
- CDH23 | c.7784C>T p.T2595I | Missense Mutation (SNP) | VAF 210/497 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs866303282; called by muse, mutect2, varscan2
- CDK5R2 | c.682del p.Q228Rfs*136 | Frame Shift Del (DEL) | VAF 93/555 reads (17%) | catalogued as COSV56936120; called by mutect2, pindel, varscan2
- CNTNAP3 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.524); catalogued as COSV99905600; called by muse, mutect2, varscan2
- CROCC2 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as rs547603044, COSV101407873; called by muse, mutect2, varscan2
- CSMD1 | c.9116G>T p.G3039V (on ENST00000520002; = p.G3038V on NM_033225.6) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866715932; called by muse, mutect2, varscan2
- CSMD3 | c.7733G>T p.G2578V (on ENST00000297405 / NM_001363185.1; = p.G2474V on NM_052900.3) | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177476; called by muse, mutect2, varscan2
- CSMD3 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52121622; called by muse, mutect2, varscan2
- DAAM2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV51314042; called by muse, mutect2
- DCAF4L2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV60476952, COSV60481637; called by muse, mutect2, varscan2
- DDX53 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60070471; called by muse, mutect2, varscan2
- DHCR24 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 57/422 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64875348; called by muse, mutect2, varscan2
- DLGAP2 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV70093836; called by muse, mutect2, varscan2
- DSPP | c.3566G>A p.S1189N | Missense Mutation (SNP) | VAF 66/1102 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.827); catalogued as COSV99217497; called by muse, mutect2
- ECPAS | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52191946; called by muse, mutect2
- EEF2K | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV53778147; called by muse, mutect2, varscan2
- ELP4 | c.333T>G p.H111Q | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as rs773338279; called by muse, mutect2, varscan2
- ESRRG | c.915G>A p.W305* | Nonsense Mutation (SNP) | VAF 71/277 reads (26%) | catalogued as COSV100753608, COSV63161144; called by muse, mutect2, varscan2
- EYS | c.72T>A p.C24* | Nonsense Mutation (SNP) | VAF 41/184 reads (22%) | catalogued as COSV60983879; called by muse, mutect2, varscan2
- FAM153B | c.718G>T p.D240Y (on ENST00000253490; = p.D163Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.843); catalogued as COSV53686145; called by muse, mutect2, varscan2
- FAM71B | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.061); catalogued as rs753781161, COSV57227593; called by muse, mutect2, varscan2
- FBXL7 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61649228; called by muse, mutect2, varscan2
- FBXO10 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52836302; called by muse, mutect2
- FERD3L | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs202202177, COSV51762449; called by muse, mutect2, varscan2
- GALNTL6 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1322274611; called by muse, mutect2, varscan2
- GDF5 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 204/742 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as COSV65501007; called by mutect2, varscan2
- GLYATL2 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV54851495; called by muse, mutect2, varscan2
- GPR32 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.798); catalogued as COSV54514373; called by muse, mutect2, varscan2
- GPRC5B | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 108/543 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV56027784; called by muse, mutect2, varscan2
- GRK1 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); catalogued as COSV100175266; called by muse, mutect2, varscan2
- IFT140 | c.2959C>G p.L987V | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV54154684; called by muse, mutect2, varscan2
- IGF2 | c.394G>T p.D132Y (on ENST00000434045 / NM_001127598.3; = p.D76Y on NM_000612.6) | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56099331; called by muse, mutect2, varscan2
- IGHV6-1 | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs782259705; called by muse, mutect2, varscan2
- IGKV1D-16 | c.133dup p.C45Lfs*8 | Frame Shift Ins (INS) | VAF 96/541 reads (18%) | catalogued as rs766693631; called by mutect2, pindel, varscan2
- IQUB | c.1023G>T p.A341= | Splice Region (SNP) | VAF 17/194 reads (9%) | catalogued as rs770600817, COSV61236550; called by muse, mutect2
- ITGA9 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV99292700; called by muse, mutect2, varscan2
- ITGAX | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1490191771; called by muse, mutect2, varscan2
- KIF5C | c.2687G>T p.R896L | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs756942747, COSV68480840; called by muse, mutect2, varscan2
- KIR3DL1 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.928); catalogued as COSV100428179; called by muse, mutect2, varscan2
- LHX5 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99028187; called by muse, mutect2, varscan2
- MPDZ | c.3901C>A p.P1301T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs200311014; called by muse, mutect2, varscan2
- MPPED1 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61986906; called by muse, mutect2, varscan2
- MROH5 | c.731G>T p.W244L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs750750413; called by muse, mutect2, varscan2
- MTCL1 | c.4639G>C p.G1547R (on ENST00000306329 / NM_001378206.1; = p.G1228R on NM_015210.4) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV100095427; called by muse, mutect2, varscan2
- MUC17 | c.9967C>A p.P3323T | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.341); catalogued as rs776263466; called by muse, mutect2, varscan2
- MYEF2 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1401089537; called by muse, mutect2, varscan2
- NBEAL2 | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.375); catalogued as rs781185845, COSV52757804; called by muse, mutect2
- NEK4 | c.1937del p.G646Efs*36 | Frame Shift Del (DEL) | VAF 46/167 reads (28%) | catalogued as COSV99238041; called by mutect2, pindel, varscan2
- NIN | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV55399493; called by muse, mutect2, varscan2
- NLRP3 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 104/360 reads (29%) | catalogued as COSV60229975; called by muse, varscan2
- NMUR2 | c.786C>A p.C262* | Nonsense Mutation (SNP) | VAF 36/99 reads (36%) | catalogued as rs764245339; called by muse, mutect2, varscan2
- NOVA2 | c.1283C>A p.T428K | Missense Mutation (SNP) | VAF 137/552 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54358937; called by muse, mutect2, varscan2
- NR1H4 | c.215C>A p.S72Y (on ENST00000551379 / NM_001206993.2; = p.S62Y on NM_005123.4) | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV51849579; called by muse, mutect2, varscan2
- OBSCN | c.8911C>T p.R2971W | Missense Mutation (SNP) | VAF 172/550 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1015246918, COSV99485777; called by muse, mutect2, varscan2
- OLFM3 | c.473C>A p.P158H (on ENST00000338858 / NM_001288821.1; = p.P138H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58795523; called by muse, mutect2, varscan2
- OR10S1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101602514; called by muse, mutect2, varscan2
- OR11H12 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs140527537; called by muse, mutect2, varscan2
- OR2M5 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV63546090, COSV63546674; called by muse, mutect2
- OR2T10 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100393641, COSV57896246; called by muse, mutect2
- OR2T33 | c.954del p.R318Sfs*19 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as COSV58815664; called by mutect2, pindel, varscan2
- OR2T5 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 36/417 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751102516, COSV63540989; called by muse, mutect2, varscan2
- OR4A5 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60521518; called by muse, mutect2, varscan2
- OR4C46 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV60219992, COSV99080380; called by muse, mutect2, varscan2
- OR5D14 | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as rs747935351, COSV99045917; called by muse, mutect2, varscan2
- OR6B1 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV68770053; called by muse, mutect2
- OR6K6 | c.805G>T p.A269S (on ENST00000368144; = p.A245S on NM_001005184.1) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.474); catalogued as COSV63745166; called by muse, mutect2, varscan2
- PAAF1 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 16/153 reads (10%) | catalogued as COSV100142599; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1001C>A p.A334E (on ENST00000374531 / NM_001037293.2; = p.A366E on NM_053016.6) | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57128427; called by muse, mutect2, varscan2
- PCDH15 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 214/455 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV57366673; called by muse, mutect2, varscan2
- PCDHGA6 | c.1836C>A p.S612R | Missense Mutation (SNP) | VAF 147/405 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs746123042; called by muse, mutect2, varscan2
- PDHA2 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54777014; called by muse, mutect2
- PDP1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV99892981; called by muse, mutect2, varscan2
- PGBD1 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99460397; called by muse, mutect2, varscan2
- POU2F1 | c.79G>T p.D27Y (on ENST00000541643 / NM_001365848.1; = p.D50Y on NM_002697.4) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1477382909, COSV54826299; called by muse, mutect2, varscan2
- PTPN7 | c.124C>A p.R42= (on ENST00000495688; = p.R81= on NM_002832.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 16/151 reads (11%) | catalogued as rs200332945, COSV58311526, COSV58313174; called by muse, mutect2, varscan2
- QSER1 | c.350G>T p.R117L (on ENST00000399302; = p.R246L on NM_001076786.3) | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV67901874; called by muse, mutect2, varscan2
- RALYL | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as rs1050792004; called by muse, varscan2
- REG3A | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59411481; called by muse, mutect2, varscan2
- RYR2 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.144); catalogued as COSV100767701; called by muse, mutect2, varscan2
- RYR2 | c.10622C>A p.T3541N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1169415432; called by muse, mutect2
- S1PR4 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99859478; called by muse, mutect2, varscan2
- SEMA5A | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV66794097; called by muse, mutect2, varscan2
- SEMA5A | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 91/365 reads (25%) | catalogued as COSV101228731; called by muse, mutect2, varscan2
- SLC2A10 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 136/524 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771851596; called by muse, mutect2, varscan2
- SLC9A6 | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.059); catalogued as COSV65788481; called by muse, mutect2
- SMPD4 | c.2462C>T p.S821L (on ENST00000409031 / NM_017951.4; = p.S792L on NM_017751.4) | Missense Mutation (SNP) | VAF 108/546 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1432615634, COSV100302661; called by muse, varscan2
- SPATA31A6 | c.1983G>T p.R661S | Missense Mutation (SNP) | VAF 138/614 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100253089; called by muse, mutect2, varscan2
- SPATA31E1 | c.2870G>C p.G957A | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57794535; called by muse, mutect2, varscan2
- SPHKAP | c.2031G>T p.R677S | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs553600575; called by muse, mutect2, varscan2
- SPOPL | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.991); catalogued as rs753118802, COSV54513944; called by muse, varscan2
- STAP1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751261091; called by muse, mutect2, varscan2
- SUN5 | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1029426531; called by muse, mutect2, varscan2
- TEX26 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 56/193 reads (29%) | catalogued as COSV66839730; called by muse, mutect2, varscan2
- TINAG | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.824); catalogued as COSV52513286, COSV99450709; called by muse, mutect2, varscan2
- TMEM200C | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs771229992; called by muse, mutect2, varscan2
- TRPC5 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV53285594; called by muse, mutect2, varscan2
- UCHL3 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66459200; called by muse, mutect2, varscan2
- VN1R5 | c.207C>A p.F69L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs976676793; called by muse, mutect2, varscan2
- VWF | c.8360A>T p.H2787L | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs765259491; called by muse, mutect2, varscan2
- WDFY3 | c.6863C>T p.S2288L | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV55692204; called by muse, mutect2
- ZFHX4 | c.7605G>T p.M2535I | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as rs750942402; called by muse, mutect2, varscan2
- ZNF282 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 90/275 reads (33%) | catalogued as COSV50479064; called by muse, mutect2, varscan2
- ZNF33A | c.1688A>G p.H563R (on ENST00000458705 / NM_006974.3; = p.H564R on NM_006954.2) | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.86); catalogued as rs184882986; called by muse, mutect2, varscan2
- ZNF534 | c.1889G>C p.R630P (on ENST00000332323 / NM_001143939.3; = p.R617P on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.117); catalogued as COSV56521912, COSV99040483; called by muse, mutect2, varscan2
- ZSCAN5C | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.855); catalogued as rs771189828; called by muse, mutect2, varscan2
- ABCA12 | c.2415G>T p.L805F (on ENST00000272895 / NM_173076.3; = p.L487F on NM_015657.3) | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ABCA7 | c.4205G>A p.G1402D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ABCB1 | c.2543T>G p.I848S | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ABCD3 | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC018630.4 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM2 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ADAMDEC1 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS18 | c.1499A>T p.Q500L | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS5 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- AGBL2 | c.1861A>C p.M621L | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- AIPL1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- AKAP9 | c.714A>T p.L238F | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ALDH2 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- AMDHD1 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD16 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD30B | c.3958G>A p.A1320T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ANKRD49 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ANKS1B | c.3267G>T p.R1089= (on ENST00000547776 / NM_152788.4; = p.R255= on NM_020140.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- ARAP1 | c.2341C>A p.L781M (on ENST00000393609 / NM_001040118.2; = p.L536M on NM_015242.4) | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASB10 | c.575G>T p.G192V (on ENST00000420175 / NM_001142459.2; = p.G177V on NM_080871.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ATRX | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- BSN | c.11357G>T p.G3786V | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BTBD17 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BZW1 | c.71_74del p.K24Rfs*16 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- C11orf86 | c.346T>G p.*116Eext*8 | Nonstop Mutation (SNP) | VAF 68/214 reads (32%) | called by muse, mutect2, varscan2
- C6orf132 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- CACNA1H | c.4006A>T p.T1336S | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CARF | c.1777G>T p.G593* | Nonsense Mutation (SNP) | VAF 53/267 reads (20%) | called by muse, mutect2, varscan2
- CARMIL1 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); called by muse, mutect2
- CATSPERE | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CCDC106 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC83 | c.1209C>A p.H403Q (on ENST00000342404 / NM_001286159.2; = p.H434Q on NM_173556.5) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CCDC93 | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCKBR | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, varscan2
- CDCP2 | c.649T>A p.Y217N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- CDH23 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 148/284 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH6 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- CDH7 | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDK11A | c.1231C>G p.P411A (on ENST00000378633 / NM_001313896.2; = p.P408A on NM_024011.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CEP170 | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2
- CFAP99 | c.4C>A p.P2T (on ENST00000506607; = p.P487T on NM_001193282.3) | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CHM | c.322T>A p.L108M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- COL11A1 | c.3934G>T p.G1312C | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- COL4A5 | c.3328G>T p.G1110* | Nonsense Mutation (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- COL6A1 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- COL6A5 | c.5072C>A p.P1691H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- COL6A6 | c.1680del p.R561Efs*20 | Frame Shift Del (DEL) | VAF 39/111 reads (35%) | called by mutect2, pindel, varscan2
- COL8A2 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CREB5 | c.1307del p.L436* (on ENST00000357727 / NM_182898.4; = p.L429* on NM_004904.3) | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- CSMD2 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSMD3 | c.2983G>A p.G995S (on ENST00000297405 / NM_001363185.1; = p.G891S on NM_052900.3) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTRB2 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CUBN | c.6920C>T p.S2307F | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCAF1 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DHX37 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DICER1 | c.4428T>G p.D1476E | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.253); called by muse, varscan2
- DLG5 | c.4538G>T p.G1513V | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNMT3B | c.1256A>T p.Q419L | Missense Mutation (SNP) | VAF 129/472 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DSC3 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DZIP1L | c.501+1G>T p.X167_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- EFS | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ESRRG | c.916A>T p.M306L | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ESX1 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ETV1 | c.1427T>A p.V476E | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- FAM153A | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FAM47B | c.835G>T p.G279* | Nonsense Mutation (SNP) | VAF 93/227 reads (41%) | called by muse, mutect2, varscan2
- FAT3 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL1 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FFAR1 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 327/772 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FFAR3 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 50/642 reads (8%) | called by muse, mutect2
- FHAD1 | c.3133G>T p.V1045L | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- G6PD | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 150/299 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GHR | c.1786del p.T596Pfs*5 | Frame Shift Del (DEL) | VAF 65/238 reads (27%) | called by mutect2, pindel, varscan2
- GIPC3 | c.763A>T p.M255L | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- GLI1 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GLYAT | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN2B | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- GRM6 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 146/446 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HEATR1 | c.1686A>T p.Q562H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HSD11B1 | c.232del p.C78Afs*19 | Frame Shift Del (DEL) | VAF 40/322 reads (12%) | called by mutect2, pindel, varscan2
- HSPA8 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 69/415 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHG2 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 66/668 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ITGAX | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITPR2 | c.7781A>T p.Y2594F | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.435); called by muse, varscan2
- IZUMO3 | c.632del p.S211Cfs*2 (on ENST00000543880 / NM_001365008.2; = p.S205Cfs*2 on NM_001271706.1) | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- JPH2 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2
- KCNG3 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- KCNJ14 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by mutect2, varscan2
- KCNT2 | c.3376G>C p.G1126R | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, varscan2
- KCTD19 | c.3+5G>C | Splice Region (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- KEL | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 75/301 reads (25%) | called by muse, mutect2, varscan2
- KIAA0100 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- KIAA1522 | c.367G>T p.E123* (on ENST00000373480 / NM_001198972.2; = p.E182* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 35/229 reads (15%) | called by muse, mutect2, varscan2
- KIAA2012 | c.2813C>G p.A938G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.2); called by muse, varscan2
- KIF21B | c.1767+1G>T p.X589_splice | Splice Site (SNP) | VAF 35/249 reads (14%) | called by muse, mutect2, varscan2
- KIF21B | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 114/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21B | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 119/474 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL42 | c.1066+5G>T | Splice Region (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- KRT13 | c.1082A>C p.Q361P | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- KRT31 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 204/771 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP4-6 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- LAMB4 | c.3886C>A p.Q1296K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LDB2 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LETM2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- LPIN2 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC69 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LRRC8A | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by mutect2, varscan2
- LSAMP | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- MAGEC3 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K9 | c.2468T>A p.L823Q (on ENST00000554752 / NM_001284230.1; = p.L837Q on NM_033141.4) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MFAP5 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMEL1 | c.1606T>C p.Y536H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MPDZ | c.5229A>G p.K1743= | Splice Region (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- MTOR | c.5638T>C p.Y1880H | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.532); called by muse, mutect2
- MUC12 | c.10868C>T p.A3623V (on ENST00000379442; = p.A3480V on NM_001164462.1) | Missense Mutation (SNP) | VAF 110/1989 reads (6%) | SIFT tolerated (0.07); called by muse, mutect2
- MYT1L | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, varscan2
- NAV3 | c.6317T>A p.L2106Q (on ENST00000397909 / NM_001024383.2; = p.L2084Q on NM_014903.6) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NKX6-3 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRG3 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 167/408 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NTNG1 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NTNG1 | c.839A>T p.H280L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- OR2AJ1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OR2M3 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- OR2T10 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2
- OR4B1 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4C46 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR5B2 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- OR6Y1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OSBPL8 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 49/168 reads (29%) | called by muse, mutect2, varscan2
- OTUD7B | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OVCH1 | c.3262G>T p.V1088L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OVCH1 | c.2339G>C p.G780A | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- P2RY8 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDH10 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA12 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2
- PCDHGB4 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PDE10A | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PDE4B | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDSS1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PEG3 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PFKFB4 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 61/191 reads (32%) | PolyPhen benign (0.354); called by muse, mutect2, varscan2
- PFKFB4 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 69/214 reads (32%) | PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PIP | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- PKD1L2 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKN2 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by mutect2, varscan2
- PLCB4 | c.2630_2631delinsT p.K877Mfs*9 | Frame Shift Del (DEL) | VAF 33/222 reads (15%) | called by pindel, varscan2*
- PLVAP | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PLXDC2 | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLXNA2 | c.1188+1G>T p.X396_splice | Splice Site (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- POT1 | c.1572G>T p.W524C | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POTEG | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 83/2085 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.576); called by muse, mutect2
- POU3F1 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R7 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PPP2R2C | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- PPP2R5D | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R3B | c.1593C>A p.N531K (on ENST00000616407 / NM_001122964.3; = p.N499K on NM_020463.4) | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- PRKCG | c.396C>A p.S132= | Splice Region (SNP) | VAF 53/277 reads (19%) | called by muse, mutect2, varscan2
- PSMD12 | c.1084-4C>G | Splice Region (SNP) | VAF 27/116 reads (23%) | called by muse, mutect2, varscan2
- PTPRK | c.2933C>A p.S978Y (on ENST00000368215 / NM_001291984.2; = p.S979Y on NM_002844.4) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRU | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- R3HDM2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, varscan2
- RAB8A | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 152/421 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RASEF | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- RASGRP2 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RBM28 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- RBPJL | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.155); called by muse, mutect2
- RCVRN | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RELN | c.5780G>C p.W1927S | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RGS13 | c.200G>C p.C67S | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMS1 | c.2323G>T p.G775* | Nonsense Mutation (SNP) | VAF 26/210 reads (12%) | called by muse, varscan2
- ROBO2 | c.3169A>T p.N1057Y | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RRP1B | c.120G>C p.Q40H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RSF1 | c.3132A>C p.G1044= | Splice Region (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- RYR2 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SBF2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1G | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- SERPINC1 | c.1153+2T>C p.X385_splice | Splice Site (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- SGCZ | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SH2B3 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SH2D3C | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHISA9 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 118/544 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIGLEC5 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 78/335 reads (23%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1054-1G>T p.X352_splice | Splice Site (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SLC25A12 | c.1918A>G p.R640G | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SLC30A3 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 108/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A12 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 97/307 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC52A1 | c.1299C>G p.Y433* | Nonsense Mutation (SNP) | VAF 97/239 reads (41%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1251G>T p.M417I | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); called by muse, varscan2
- SOWAHC | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- SOX11 | c.1251C>A p.C417* | Nonsense Mutation (SNP) | VAF 58/256 reads (23%) | called by muse, mutect2, varscan2
- SOX30 | c.2104C>G p.H702D | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SP100 | c.2594A>T p.E865V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- SP140 | c.74T>G p.I25S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- SP4 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SPATA13 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAB1 | c.7644T>A p.C2548* | Nonsense Mutation (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- STRIP2 | c.467G>C p.C156S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULF2 | c.443A>T p.Y148F | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SVEP1 | c.9031G>T p.V3011L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SVEP1 | c.5967C>A p.C1989* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- SYNE1 | c.17220T>A p.Y5740* (on ENST00000367255 / NM_182961.4; = p.Y5669* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
- SYTL2 | c.1424A>T p.Q475L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- TACC1 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 29/301 reads (10%) | called by muse, mutect2
- TAGAP | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS1R1 | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TDRD12 | c.3107T>C p.L1036P (on ENST00000444215; = p.L1041P on NM_001366102.1) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TDRD15 | c.116G>C p.C39S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TMEM178B | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAPPC8 | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, varscan2
- TRIM51GP | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 72/349 reads (21%) | called by muse, mutect2, varscan2
- TRIM64B | c.112T>A p.C38S | Missense Mutation (SNP) | VAF 26/620 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM64C | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRPM2 | c.583del p.V195Sfs*21 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- TRPM3 | c.1279-1G>T p.X427_splice (on ENST00000357533 / NM_001366142.2; = p.X272_splice on NM_020952.6) | Splice Site (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- TTC33 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 60/194 reads (31%) | called by muse, mutect2, varscan2
- TTC34 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2D1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- UGT1A4 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- USP24 | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- VSTM2B | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWF | c.7706C>G p.A2569G | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR87 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 89/272 reads (33%) | called by muse, mutect2, varscan2
- WNK3 | c.596A>T p.K199M | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWP1 | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED8 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZFC3H1 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZFHX4 | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | called by muse, mutect2, varscan2
- ZMAT1 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF131 | c.620A>C p.D207A | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZNF341 | c.1529A>G p.K510R (on ENST00000375200 / NM_001282935.1; = p.K503R on NM_032819.4) | Missense Mutation (SNP) | VAF 110/387 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF479 | c.1526C>A p.A509D | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ZNF569 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF845 | c.2326A>T p.K776* | Nonsense Mutation (SNP) | VAF 14/153 reads (9%) | called by muse, mutect2
- ZSCAN12 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZSCAN18 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 30/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCG2 | c.15T>C p.N5= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs777052388; called by muse, mutect2, varscan2
- ABCG8 | c.1935C>G p.L645= | Silent (SNP) | VAF 27/486 reads (6%) | called by muse, mutect2
- ADAMTS12 | c.2568C>A p.R856= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as rs562347214, COSV61267691; called by muse, mutect2, varscan2
- ADAMTS12 | c.670C>A p.R224= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs144784477, COSV100711660; called by muse, mutect2
- ADAMTS3 | c.2328C>A p.T776= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as COSV99711862; called by muse, mutect2
- ADGRA2 | c.628C>T p.L210= | Silent (SNP) | VAF 40/385 reads (10%) | called by muse, mutect2, varscan2
- AGAP9 | c.1113G>T p.L371= | Silent (SNP) | VAF 306/1335 reads (23%) | called by mutect2, varscan2
- ANKRD30A | c.963G>T p.V321= (on ENST00000611781; = p.V265= on NM_052997.2) | Silent (SNP) | VAF 132/378 reads (35%) | called by muse, mutect2, varscan2
- APC | c.6276A>T p.L2092= | Silent (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- APOLD1 | c.531C>T p.G177= (on ENST00000326765 / NM_001130415.2; = p.G146= on NM_030817.3) | Silent (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- ASTN2 | c.615C>A p.L205= | Silent (SNP) | VAF 49/247 reads (20%) | called by muse, mutect2, varscan2
- AXDND1 | c.2604A>C p.A868= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- CACNA1H | c.4008G>T p.T1336= | Silent (SNP) | VAF 34/256 reads (13%) | catalogued as rs372696265; called by muse, mutect2
- CCKBR | c.1044A>T p.P348= | Silent (SNP) | VAF 136/640 reads (21%) | called by muse, varscan2
- CD300LF | c.456C>A p.L152= | Silent (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- CDH8 | c.1758G>C p.L586= | Silent (SNP) | VAF 88/598 reads (15%) | called by muse, mutect2, varscan2
- CDH9 | c.2265T>A p.S755= | Silent (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- CDH9 | c.1710C>A p.I570= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as rs772941002, COSV50296960, COSV99142905; called by muse, varscan2
- CELF4 | c.666G>T p.S222= | Silent (SNP) | VAF 98/284 reads (35%) | catalogued as COSV58467450; called by muse, mutect2, varscan2
- CFH | c.420A>T p.I140= | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- CLEC1B | c.156G>A p.G52= | Silent (SNP) | VAF 18/241 reads (7%) | catalogued as rs777563676; called by muse, mutect2
- CLEC3B | c.522G>T p.A174= | Silent (SNP) | VAF 91/253 reads (36%) | catalogued as COSV56109672; called by muse, mutect2, varscan2
- CMA1 | c.552T>C p.N184= | Silent (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- COL4A5 | c.1563T>A p.G521= | Silent (SNP) | VAF 67/225 reads (30%) | called by muse, varscan2
- DBH | c.672C>A p.P224= | Silent (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- DLGAP3 | c.630C>T p.S210= | Silent (SNP) | VAF 84/261 reads (32%) | called by muse, mutect2, varscan2
- DMTF1 | c.1371C>A p.P457= | Silent (SNP) | VAF 50/301 reads (17%) | called by muse, mutect2, varscan2
- DRD5 | c.1332C>A p.S444= | Silent (SNP) | VAF 62/209 reads (30%) | catalogued as COSV100431491; called by muse, mutect2, varscan2
- ECEL1 | c.2103C>A p.P701= | Silent (SNP) | VAF 55/288 reads (19%) | catalogued as COSV100458784; called by muse, mutect2, varscan2
- EFS | c.1560G>T p.L520= | Silent (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- EIF3I | c.9G>T p.P3= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- ENPP7 | c.615C>T p.Y205= | Silent (SNP) | VAF 52/285 reads (18%) | catalogued as rs138491235; called by muse, mutect2, varscan2
- EPHB4 | c.2850C>T p.I950= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1173336501, COSV62268698; called by muse, mutect2
- ERCC6L2 | c.417C>T p.I139= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- FAM71B | c.1266T>A p.A422= | Silent (SNP) | VAF 90/245 reads (37%) | called by muse, mutect2, varscan2
- FMR1 | c.1788G>A p.Q596= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- FURIN | c.1305G>T p.V435= | Silent (SNP) | VAF 127/426 reads (30%) | called by muse, mutect2, varscan2
- GABRB3 | c.963T>A p.L321= | Silent (SNP) | VAF 98/343 reads (29%) | called by muse, varscan2
- GP2 | c.699G>A p.E233= (on ENST00000381362 / NM_001007240.3; = p.E230= on NM_001502.4) | Silent (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- GPRC5B | c.454C>A p.R152= | Silent (SNP) | VAF 62/347 reads (18%) | called by muse, mutect2, varscan2
- GRPEL2 | c.531G>A p.E177= | Silent (SNP) | VAF 71/233 reads (30%) | called by muse, mutect2, varscan2
- HERC1 | c.8757G>T p.G2919= | Silent (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- HHIP | c.1191G>T p.V397= | Silent (SNP) | VAF 81/176 reads (46%) | called by muse, mutect2, varscan2
- HMX1 | c.249C>A p.A83= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- HTR1B | c.666G>T p.L222= | Silent (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- IGLL1 | c.408C>T p.L136= | Silent (SNP) | VAF 210/473 reads (44%) | called by muse, mutect2, varscan2
- INPP5B | c.591G>C p.A197= | Silent (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- IRF8 | c.1050T>C p.F350= | Silent (SNP) | VAF 101/640 reads (16%) | called by muse, mutect2, varscan2
- KANK4 | c.999C>T p.G333= | Silent (SNP) | VAF 74/194 reads (38%) | catalogued as COSV100587339; called by muse, mutect2, varscan2
- KIR3DL2 | c.813G>A p.K271= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- KLK3 | c.57C>A p.P19= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV100386082, COSV58102806; called by muse, mutect2
- KPNB1 | c.1530C>G p.L510= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV51597367; called by muse, varscan2
- LOXHD1 | c.1413C>A p.G471= | Silent (SNP) | VAF 36/108 reads (33%) | called by muse, varscan2
- LRP1B | c.1906C>A p.R636= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV67199923; called by muse, mutect2, varscan2
- LRP8 | c.825G>T p.L275= | Silent (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1206G>C p.R402= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100598410, COSV63048278; called by muse, mutect2, varscan2
- LYST | c.4218C>T p.S1406= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- MAGEB18 | c.405G>A p.K135= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs1246868074; called by muse, mutect2, varscan2
- MMP17 | c.771C>T p.S257= | Silent (SNP) | VAF 150/488 reads (31%) | catalogued as rs1289026354; called by muse, mutect2, varscan2
- MUC19 | c.636G>T p.G212= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, varscan2
- MUC6 | c.1317C>T p.Y439= | Silent (SNP) | VAF 50/385 reads (13%) | catalogued as rs745628982, COSV70142876; called by muse, mutect2, varscan2
- MVB12A | c.777G>T p.V259= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- MYBPC2 | c.528G>T p.S176= | Silent (SNP) | VAF 39/245 reads (16%) | called by muse, mutect2, varscan2
- MYO1H | c.2316T>C p.S772= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- NALCN | c.2280C>A p.I760= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs753283222, COSV51941361; called by muse, mutect2, varscan2
- NLRP3 | c.12C>A p.T4= | Silent (SNP) | VAF 49/298 reads (16%) | called by muse, mutect2, varscan2
- NLRP3 | c.642T>C p.S214= | Silent (SNP) | VAF 108/366 reads (30%) | called by muse, mutect2, varscan2
- NLRP4 | c.2109C>T p.L703= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- NOX3 | c.819C>A p.G273= | Silent (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- NOX4 | c.879G>C p.L293= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- NTSR2 | c.574C>A p.R192= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs755644028; called by muse, mutect2, varscan2
- OR1C1 | c.237C>A p.P79= | Silent (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- OR56A4 | c.972T>A p.P324= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs759329438; called by muse, mutect2, varscan2
- OR5M10 | c.138C>A p.I46= | Silent (SNP) | VAF 103/446 reads (23%) | catalogued as rs777225905, COSV73242419; called by muse, mutect2, varscan2
- OR9A4 | c.546G>T p.G182= | Silent (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- PADI3 | c.1089C>A p.T363= | Silent (SNP) | VAF 31/220 reads (14%) | called by muse, mutect2, varscan2
- PARD6G | c.1119G>T p.A373= | Silent (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1359G>T p.P453= | Silent (SNP) | VAF 195/473 reads (41%) | catalogued as COSV65364264; called by muse, mutect2, varscan2
- PDZRN4 | c.3102C>A p.T1034= (on ENST00000402685 / NM_001164595.2; = p.T776= on NM_013377.4) | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- PGLYRP4 | c.888C>A p.S296= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV100668318; called by muse, mutect2, varscan2
- PHOX2B | c.192C>T p.S64= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- PIAS4 | c.1320G>C p.G440= | Silent (SNP) | VAF 21/416 reads (5%) | called by muse, mutect2
- PLCB1 | c.1431C>T p.S477= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs758504402, COSV62052315; called by muse, varscan2
- POLE | c.2343G>T p.A781= | Silent (SNP) | VAF 80/221 reads (36%) | called by muse, mutect2, varscan2
- POTEE | c.2256C>A p.S752= | Silent (SNP) | VAF 104/674 reads (15%) | called by muse, mutect2, varscan2
- PRPF4 | c.345G>T p.G115= (on ENST00000374198 / NM_001322267.2; = p.G116= on NM_004697.5) | Silent (SNP) | VAF 35/203 reads (17%) | called by muse, mutect2, varscan2
- PRSS38 | c.186C>A p.G62= | Silent (SNP) | VAF 90/232 reads (39%) | catalogued as rs369177689; called by muse, mutect2, varscan2
- RAPGEFL1 | c.342C>T p.L114= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1433121041, COSV52862916; called by muse, mutect2
- RGPD3 | c.2556G>C p.V852= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100450647; called by mutect2, varscan2
- RP1 | c.282C>A p.R94= | Silent (SNP) | VAF 155/422 reads (37%) | called by muse, mutect2, varscan2
- RP1L1 | c.1746A>T p.S582= | Silent (SNP) | VAF 129/420 reads (31%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1599G>T p.P533= | Silent (SNP) | VAF 58/272 reads (21%) | called by muse, mutect2, varscan2
- SOWAHC | c.708C>T p.G236= | Silent (SNP) | VAF 72/306 reads (24%) | called by muse, mutect2
- SRCAP | c.2061A>G p.K687= | Silent (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- STYXL2 | c.1005C>T p.A335= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- TACC1 | c.36G>T p.V12= | Silent (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2
- TBCD | c.1278G>T p.L426= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- TERT | c.1695G>A p.E565= | Silent (SNP) | VAF 69/586 reads (12%) | catalogued as COSV57243900; called by muse, mutect2, varscan2
- TMEM63C | c.390C>T p.R130= | Silent (SNP) | VAF 28/203 reads (14%) | called by muse, mutect2, varscan2
- TMTC4 | c.526C>T p.L176= (on ENST00000376234 / NM_001350577.2; = p.L195= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- TNFRSF17 | c.408G>T p.P136= | Silent (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC5 | c.510C>T p.L170= | Silent (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- TRIM38 | c.693G>T p.L231= | Silent (SNP) | VAF 59/215 reads (27%) | called by muse, mutect2, varscan2
- TRIM55 | c.741G>T p.L247= | Silent (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- TRPM1 | c.2283C>A p.I761= | Silent (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- TSHZ2 | c.571C>T p.L191= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as COSV61592660; called by muse, mutect2, varscan2
- TSN | c.576G>A p.R192= | Silent (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- USH2A | c.2601A>G p.Q867= | Silent (SNP) | VAF 98/311 reads (32%) | called by muse, mutect2, varscan2
- WDFY3 | c.8082G>T p.V2694= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99882438; called by muse, mutect2, varscan2
- ZEB2 | c.3249G>T p.R1083= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- ZFHX3 | c.4518G>A p.T1506= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs753209044, COSV51722668; called by muse, mutect2, varscan2
- ZNF230 | c.993A>G p.T331= | Silent (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.960C>A p.G320= | Silent (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- ACKR1 | c.-37C>A | 5'UTR (SNP) | VAF 67/382 reads (18%) | called by muse, mutect2, varscan2
- ANKRD11 | c.-59-7506C>T | Intron (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-35C>T | Intron (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- ATG4B | chr2:241637592 C>G | 5'Flank (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38745G>T | Intron (SNP) | VAF 64/266 reads (24%) | called by mutect2, varscan2
- BRCA2 | c.8633-1305G>C | Intron (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- CARD9 | c.*14G>T | 3'UTR (SNP) | VAF 75/462 reads (16%) | called by muse, mutect2, varscan2
- CCDC144B | n.540del | RNA (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- CCDC144B | n.445G>T | RNA (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- CCDC144CP | n.3015C>T | RNA (SNP) | VAF 68/281 reads (24%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.293A>T | RNA (SNP) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- EIF4ENIF1 | c.1512+750C>A | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as rs1443704312; called by muse, mutect2
- FCRL5 | c.*31C>T | 3'UTR (SNP) | VAF 121/403 reads (30%) | called by muse, mutect2, varscan2
- GABRB3 | chr15:26773750 ins T | 5'Flank (INS) | VAF 69/239 reads (29%) | called by mutect2, pindel, varscan2
- GP1BB | chr22:19723497 G>T | 5'Flank (SNP) | VAF 98/208 reads (47%) | called by muse, mutect2, varscan2
- GUSBP10 | n.124C>A | RNA (SNP) | VAF 66/236 reads (28%) | catalogued as rs979920490; called by muse, mutect2, varscan2
- HBE1 | c.-267+102114G>T | Intron (SNP) | VAF 61/247 reads (25%) | catalogued as rs906896024; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1049A>T | Intron (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- INVS | c.273+3153G>C | Intron (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- ITGB3BP | c.-24A>G | 5'UTR (SNP) | VAF 50/325 reads (15%) | catalogued as rs763153407; called by muse, mutect2, varscan2
- JAML | c.772+398G>A | Intron (SNP) | VAF 45/435 reads (10%) | called by muse, mutect2, varscan2
- KCNU1 | c.2737-1970A>T | Intron (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- KIAA0586 | c.4450+3777G>T | Intron (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- KIF5A | c.-5C>A | 5'UTR (SNP) | VAF 72/545 reads (13%) | called by muse, mutect2, varscan2
- LINC02312 | n.566G>T | RNA (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- LINC02692 | n.216G>A | RNA (SNP) | VAF 44/205 reads (21%) | catalogued as rs553697155; called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.130C>A | RNA (SNP) | VAF 24/427 reads (6%) | called by muse, mutect2
- MIR508 | n.84G>C | RNA (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- MKS1 | chr17:58219552 C>A | 5'Flank (SNP) | VAF 55/238 reads (23%) | called by muse, mutect2, varscan2
- MTAP | c.813+2581A>G | Intron (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- MUC5B | c.*139C>A | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- NBPF7 | n.312G>T | RNA (SNP) | VAF 30/404 reads (7%) | called by muse, mutect2
- NRXN1 | c.3365-109913G>A | Intron (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- NUP133 | c.-13G>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- OFCC1 | n.86G>T | RNA (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- OPALIN | c.-29C>T | 5'UTR (SNP) | VAF 84/216 reads (39%) | catalogued as rs778657175; called by muse, mutect2, varscan2
- OR52Z1 | n.341del | RNA (DEL) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- PADI1 | c.*14C>G | 3'UTR (SNP) | VAF 77/361 reads (21%) | catalogued as COSV100968437; called by muse, mutect2, varscan2
- PGAM5P1 | chr5:109883918 A>T | 3'Flank (SNP) | VAF 80/268 reads (30%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.1633+416C>G | Intron (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- RAB6B | c.70+9806C>T | Intron (SNP) | VAF 70/191 reads (37%) | catalogued as COSV53315489; called by muse, mutect2, varscan2
- RNF112 | c.589-56C>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SAG | c.181+171C>T | Intron (SNP) | VAF 38/171 reads (22%) | catalogued as rs752294787, COSV68590927; called by muse, mutect2, varscan2
- SAG | c.1102+14T>C | Intron (SNP) | VAF 43/211 reads (20%) | catalogued as rs764670195; called by muse, mutect2, varscan2
- SLC9B1P1 | n.1214A>T | RNA (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- SON | c.6321+258G>T | Intron (SNP) | VAF 27/96 reads (28%) | catalogued as rs1163898128; called by muse, mutect2, varscan2
- SSPOP | n.10927G>T | RNA (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.10928G>C | RNA (SNP) | VAF 17/54 reads (31%) | catalogued as COSV65141000; called by muse, mutect2, varscan2
- SSPOP | n.13946G>T | RNA (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- TBX22 | c.-11C>G | 5'UTR (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100960849; called by muse, mutect2, varscan2
- TMEM135 | c.*1552G>C | 3'UTR (SNP) | VAF 97/277 reads (35%) | called by muse, mutect2, varscan2
- TNNT2 | c.489+24C>A | Intron (SNP) | VAF 77/245 reads (31%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.579-499C>G | Intron (SNP) | VAF 26/69 reads (38%) | catalogued as rs752295855; called by muse, mutect2, varscan2
- WAPL | c.-347C>T | 5'UTR (SNP) | VAF 164/424 reads (39%) | catalogued as rs896246883; called by muse, mutect2, varscan2
- XIAP | c.*6108T>G | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- XIRP2 | c.*420C>A | 3'UTR (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- ZNF589 | c.-30C>G | 5'UTR (SNP) | VAF 132/392 reads (34%) | called by muse, mutect2, varscan2
- ZNF729 | c.-36C>A | 5'UTR (SNP) | VAF 139/408 reads (34%) | called by muse, mutect2, varscan2
